Gene-level copy-number profile of specimen HCM-CSHL-0061-C18-85A from HCMI case HCM-CSHL-0061-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.0 years (22,277 days).
Specimen HCM-CSHL-0061-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ef8a3189-9306-425a-8325-d421b081cdc9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0061-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,261 have no estimate.
https://portal.gdc.cancer.gov/files/f50e4c97-c9af-4d9a-a69a-78f964622928

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 708; copy number 2: 5,668; copy number 3: 20,237; copy number 4: 21,300; copy number 5: 5,453; copy number 6: 3,131; copy number 7: 1,853; copy number 8: 4; copy number 9: 3; copy number 15: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,865 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:137,682–157,887, 3 genes, copy number 8: AL627309.7, AL627309.2, RNU6-1100P.
- chr3:125,734,295–125,748,098, 2 genes, copy number 7: OR7E53P, OR7E97P.
- chr3:130,048,143–130,055,920, 1 gene, copy number 7: AC083906.4.
- chr7:63,011,463–69,430,923, 211 genes, copy number 7 (broad region; genes not listed).
- chr7:70,837,738–73,719,672, 61 genes, copy number 7 (broad region; genes not listed).
- chr7:105,439,661–105,876,604, 8 genes, copy number 7: PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1.
- chr7:131,110,096–133,082,090, 24 genes, copy number 7 (within-gene range 4–7): MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1, AC105443.1, PLXNA4, AC018643.1, AC011625.1, FLJ40288, AC009365.1, AC009365.2, CHCHD3, AC009365.3, AC008038.1, MIR3654.
- chr7:155,222,903–159,233,377, 65 genes, copy number 7 (broad region; genes not listed).
- chr8:41,426,655–47,198,861, 98 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr14:18,601,045–18,699,978, 9 genes, copy number 8–15: OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12, CR383656.3, RPL22P20, CR383656.4.
- chr20:87,250–13,996,443, 277 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:16,177,933–64,327,972, 1,106 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 708. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
